Somatic mutation profile of tumor specimen BA3305D (aliquot aq-BA3305D) from BEATAML1.0 case 2634, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 84.8 years (30,985 days).
Specimen BA3305D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a7975f9-c312-4a90-9c11-51c7804b1395.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3096D (Solid Tissue Normal), aliquot aq-BA3096D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5858b517-7aba-499e-97e3-b276ad8d967f

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMC1A | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1569356550, COSV59131454; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CD164L2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV64995686; called by muse, mutect2
- MED12 | c.1577C>A p.A526D | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTBK1 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
